Gene-level copy-number profile of tumor specimen TCGA-D6-A74Q-01A from TCGA case TCGA-D6-A74Q, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 67.6 years (24,702 days).
Specimen TCGA-D6-A74Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.880970c7-36a6-4b7d-af71-d8277c8dbf9c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D6-A74Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/50e14135-6a88-4585-824e-9b9e0ed0fed1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,648; copy number 2: 42,072; copy number 3: 5,674; copy number 4: 24; copy number 5: 230; copy number 6: 120; copy number 8: 3; copy number 9: 11; copy number 12: 9; copy number 13: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D6-A74Q-01A-11D-A34I-01): tumor purity 0.65, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 395 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:53,647,916–55,282,620, 21 genes, copy number 5–12: KLHL31, AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2.
- chr17:22,331,597–22,706,703, 22 genes, copy number 13: AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.
- chr17:60,677,453–61,392,838, 1 gene, copy number 5 (within-gene range 2–5): BCAS3.
- chr17:61,034,636–64,662,307, 120 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:47,390–9,679,493, 195 genes, copy number 5–6 (broad region; genes not listed).
- chr18:9,734,882–9,735,602, 1 gene, copy number 5: AP000902.1.
- chr18:45,669,367–47,282,939, 35 genes, copy number 5–9 (within-gene range 3–9): AC023421.2, SLC14A1, AC087685.1, SIGLEC15, EPG5, PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25, RNF165, AC015959.1, AC018931.1, LOXHD1, ST8SIA5, AC090311.1, AC090241.2, AC090241.3, PIAS2, AC090241.1, AC090373.1, KATNAL2, AC012254.5, AC012254.1, AC012254.3, HDHD2, AC012254.2, AC012254.4, IER3IP1, SKOR2, RNU6-1131P, AC051635.1.

Autosomal genes at a single copy (total copy number 1): 9,227. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
